Somatic mutation profile of tumor specimen TCGA-D8-A13Z-01A (aliquot TCGA-D8-A13Z-01A-11D-A10Y-09) from TCGA case TCGA-D8-A13Z, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.9 years (18,942 days).
Specimen TCGA-D8-A13Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ada6011a-cff9-45fc-afee-527e54f605cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A13Z-10A (Blood Derived Normal), aliquot TCGA-D8-A13Z-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60cd4bdc-3653-4afa-8712-4b65628c4b91

The open-access MAF lists 89 somatic variants for this specimen: 75 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 13, Nonsense Mutation 3, In Frame Del 2, Splice Site 2, Frame Shift Del 2, Splice Region 2, In Frame Ins 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.3095G>A p.C1032Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137854481, CM010036, COSV57321074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRT17 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs58730926, CM110824, CM148385, CM983347, COSV60861109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 30/76 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3781G>A p.V1261M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs756405833, COSV60681529; called by muse, mutect2, varscan2
- ACAD10 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs750824318, COSV58158834; called by muse, mutect2, varscan2
- APOBR | c.399C>G p.S133R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as COSV60491657; called by muse, mutect2, varscan2
- ATP23 | c.454-2A>C p.X152_splice | Splice Site (SNP) | VAF 53/416 reads (13%) | catalogued as COSV100274426, COSV100274558; called by muse, mutect2, varscan2
- BSN | c.307A>T p.T103S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs199855668, COSV56521450; called by muse, mutect2, varscan2
- CD47 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100790104; called by muse, mutect2
- CIAO2B | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs1207559843, COSV57696161, COSV57696611; called by muse, mutect2, varscan2
- COG6 | c.605C>G p.T202R | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV62996565; called by muse, mutect2, varscan2
- COL10A1 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99684124; called by muse, mutect2
- COL18A1 | c.3402C>T p.D1134= (on ENST00000359759 / NM_130444.3; = p.D899= on NM_030582.4) | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as rs754670613, COSV60590191; called by muse, mutect2
- COL25A1 | c.328A>C p.I110L | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV67652430; called by muse, mutect2, varscan2
- DDX39A | c.39C>A p.Y13* | Nonsense Mutation (SNP) | VAF 12/97 reads (12%) | catalogued as COSV54392207; called by muse, mutect2, varscan2
- DST | c.19402G>C p.E6468Q (on ENST00000361203 / NM_001374722.1; = p.E4165Q on NM_015548.5) | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.316); catalogued as COSV99752889, COSV99758397; called by muse, mutect2
- ESPL1 | c.3535C>G p.Q1179E | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.184); catalogued as rs371853647; called by muse, mutect2, varscan2
- ESRRG | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100753182, COSV63167266; called by muse, mutect2, varscan2
- FAM118B | c.252T>G p.D84E | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64157315; called by muse, mutect2, varscan2
- FAM135A | c.868G>C p.V290L (on ENST00000370479 / NM_001351599.1; = p.V273L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.051); catalogued as COSV99525470; called by muse, mutect2
- FBL | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99695219; called by muse, mutect2
- FERD3L | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763265; called by muse, mutect2, varscan2
- GRIN2B | c.3896G>A p.R1299H | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV74205835, COSV74206521; called by muse, mutect2, varscan2
- GUCY2C | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53786584, COSV53786766; called by muse, mutect2, varscan2
- HYDIN | c.13362G>C p.Q4454H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV66639886; called by mutect2, varscan2
- INSR | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV57165642; called by muse, mutect2, varscan2
- KMT2D | c.15996G>T p.M5332I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); catalogued as COSV56456045; called by muse, mutect2, varscan2
- LAIR1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV100479520; called by mutect2, varscan2
- LAMA2 | c.7849C>A p.L2617M | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV70350723; called by muse, mutect2, varscan2
- LDLRAD3 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs758015390, COSV59684142; called by muse, mutect2, varscan2
- LRP1 | c.7624C>G p.L2542V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV54516074; called by muse, mutect2, varscan2
- LUZP1 | c.840C>G p.N280K | Missense Mutation (SNP) | VAF 56/432 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56502693; called by muse, mutect2, varscan2
- MAP3K13 | c.2338G>T p.E780* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs745553607, COSV53991301, COSV53999343; called by muse, mutect2, varscan2
- MUC1 | c.3436G>T p.V1146F (on ENST00000611571 / NM_001371720.1; = p.V157F on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV58111087, COSV58115719; called by muse, mutect2, varscan2
- NEBL | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as COSV101008900; called by muse, mutect2
- NKAIN2 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV63671087, COSV63672477; called by muse, mutect2, varscan2
- NLRP7 | c.2298G>C p.L766= (on ENST00000340844 / NM_206828.3; = p.L738= on NM_139176.3) | Splice Region (SNP) | VAF 9/58 reads (16%) | catalogued as COSV60176655; called by muse, mutect2, varscan2
- NOS1AP | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722978; called by muse, mutect2
- OR51A7 | c.149A>T p.K50M | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63788573; called by muse, mutect2, varscan2
- OR5P2 | c.260C>A p.T87K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100271242; called by muse, mutect2, varscan2
- OSMR | c.1392G>C p.K464N | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV57086988; called by muse, mutect2, varscan2
- PHF20L1 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55194611; called by muse, mutect2, varscan2
- PHLPP2 | c.3056G>A p.S1019N | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62425190; called by muse, mutect2, varscan2
- PIPOX | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs142705261; called by muse, mutect2, varscan2
- PLIN4 | c.3605A>T p.H1202L (on ENST00000301286; = p.H1217L on NM_001367868.2) | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV56693365; called by muse, mutect2, varscan2
- PRDM10 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV62604584; called by muse, mutect2, varscan2
- PSMD9 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs1410086112, COSV55839874; called by muse, mutect2, varscan2
- RCOR3 | c.1089G>C p.E363D | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100879510; called by muse, mutect2
- RICTOR | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV57124609; called by muse, varscan2
- RMND1 | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.211); catalogued as COSV100323575; called by muse, mutect2
- RRAGC | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV100883812; called by muse, mutect2
- SLC35A1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs768180522, COSV65780304; called by muse, mutect2, varscan2
- SLC6A18 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779006560, COSV57252306; called by muse, mutect2, varscan2
- ST3GAL4 | c.972G>A p.M324I (on ENST00000392669 / NM_001254758.1; = p.M320I on NM_006278.3) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57108208; called by muse, mutect2, varscan2
- SUPT20HL2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs768776878; called by muse, mutect2, varscan2
- SVIL | c.4593A>C p.K1531N (on ENST00000355867 / NM_021738.3; = p.K1105N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV63444786; called by muse, mutect2, varscan2
- TARBP2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV57199982; called by muse, mutect2, varscan2
- TKFC | c.1413G>C p.W471C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV53652530; called by muse, mutect2, varscan2
- TMBIM4 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs765685858, COSV53967824; called by muse, mutect2, varscan2
- TSKS | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.272); catalogued as COSV55876242; called by muse, mutect2, varscan2
- TUT4 | c.2245C>G p.L749V | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as COSV99931984; called by muse, mutect2, varscan2
- TUT4 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.38); catalogued as COSV57116020; called by muse, mutect2, varscan2
- TXNDC9 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99959855; called by muse, mutect2
- XPOT | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV100225408; called by muse, mutect2
- ZFR | c.3088C>G p.L1030V | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54054865, COSV99416205; called by muse, mutect2, varscan2
- ZNF526 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1208146973, COSV55899749; called by muse, mutect2, varscan2
- ZNF551 | c.1889T>G p.L630R | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56593601; called by muse, mutect2, varscan2
- ZNRF4 | c.896T>A p.V299D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV55774826; called by muse, mutect2, varscan2
- C2orf16 | c.1761_1763del p.V588del | In Frame Del (DEL) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- DELE1 | c.268_274del p.T90Pfs*24 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, varscan2
- FSIP2 | c.17426_17431dup p.D5810_R5811insKD | In Frame Ins (INS) | VAF 30/88 reads (34%) | called by mutect2, pindel, varscan2
- FYCO1 | c.55_55+1dup p.X19_splice | Splice Site (INS) | VAF 39/289 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R15A | c.1978_1993del p.S660Lfs*26 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- PTEN | c.768dup p.F257Vfs*41 | Frame Shift Ins (INS) | VAF 49/126 reads (39%) | called by mutect2, pindel, varscan2
- RAPGEF1 | c.986_995delinsT p.Y329_R332delinsL | In Frame Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2*
- EIF3F | c.777C>T p.P259= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV59142474; called by muse, mutect2, varscan2
- LRP1 | c.3648C>G p.P1216= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV54501339, COSV99675085; called by muse, mutect2
- MYH11 | c.288C>A p.L96= | Silent (SNP) | VAF 95/313 reads (30%) | catalogued as COSV55558291; called by muse, mutect2, varscan2
- NUDT3 | c.465C>T p.V155= | Silent (SNP) | VAF 26/255 reads (10%) | catalogued as rs201234064, COSV70444566; called by muse, mutect2
- NUP133 | c.1293A>T p.G431= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV99772724; called by muse, mutect2
- PCDHB8 | c.1692C>T p.Y564= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV50832306, COSV99176385; called by muse, mutect2
- RAB17 | c.471G>A p.L157= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1169791166, COSV52816244; called by muse, mutect2, varscan2
- RAD51AP2 | c.1806A>G p.E602= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1213539671, COSV101208304; called by muse, mutect2
- SENP6 | c.1329C>A p.V443= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as COSV59192130; called by muse, mutect2, varscan2
- SZT2 | c.3219C>T p.A1073= (on ENST00000634258 / NM_001365999.1; = p.A1016= on NM_015284.4) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1385866926, COSV65167126; called by muse, mutect2, varscan2
- TENM2 | c.6999C>A p.T2333= (on ENST00000518659 / NM_001122679.2; = p.T2094= on NM_001080428.3) | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as COSV69133976; called by muse, mutect2, varscan2
- TPH2 | c.300G>C p.R100= | Silent (SNP) | VAF 27/230 reads (12%) | catalogued as COSV61592724, COSV61593860; called by muse, mutect2, varscan2
- WDR7 | c.2904T>C p.P968= | Silent (SNP) | VAF 9/215 reads (4%) | catalogued as COSV99588964; called by muse, mutect2
- DST | c.4297-3830C>A | Intron (SNP) | VAF 20/320 reads (6%) | catalogued as COSV99752894; called by muse, mutect2
